Somatic mutation profile of tumor specimen TCGA-HT-7680-01A (aliquot TCGA-HT-7680-01A-11D-2253-08) from TCGA case TCGA-HT-7680, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 32.8 years (11,970 days).
Specimen TCGA-HT-7680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb8e387d-69fe-440e-bb18-06a847d32fa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7680-10A (Blood Derived Normal), aliquot TCGA-HT-7680-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95889c88-2568-47eb-91de-6fafaa45e279

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRR12 | c.2219C>T p.T740M (on ENST00000615927; = p.T1561M on NM_020719.3) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV69819340; called by muse, mutect2, varscan2
- CD244 | c.510C>T p.Y170= (on ENST00000368033 / NM_001166663.2; = p.Y165= on NM_016382.4) | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as COSV59240210; called by muse, mutect2, varscan2
- INSRR | c.552G>A p.L184= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV63876099; called by muse, mutect2, varscan2
